MMRF case MMRF_2760 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/999b54c1-4ece-43ae-ae59-14d76a33dbbb

Demographics
Sex at birth: female; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: I; Days to last known disease status: 161 days; Days to last follow up: 161 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -24, day 161.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Absolute Neutrophil 3.6 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL.
- Platelets 246 ×10⁹/L.
- Creatinine 85.7 µmol/L.
- Beta 2 Microglobulin 3.3 µg/mL.
- Albumin 46.8 g/L.
- Hemoglobin 9.24 mmol/L.
- Lactate Dehydrogenase 5.77 µkat/L.
- Calcium 2.77 mmol/L.
- M Protein 0.1 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 55.5 mg/dL.

Other clinical attributes
- Day -24: Weight: 84 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_2760_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_2760_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
